Somatic mutation profile of tumor specimen TARGET-15-SJMPAL017976-09A.3 (aliquot TARGET-15-SJMPAL017976-09A.3-01D) from TARGET case TARGET-15-SJMPAL017976, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.7 years (5,022 days).
Specimen TARGET-15-SJMPAL017976-09A.3: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e258ede-134a-4f5a-a180-2a175e798b27.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL017976-10A (Blood Derived Normal), aliquot TARGET-15-SJMPAL017976-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b929ab2-0e78-482c-a5fa-3bb34dd0144f

The open-access MAF lists 22 somatic variants for this specimen: 18 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Nonsense Mutation 4, Silent 3, Frame Shift Ins 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.2893C>T p.R965* | Nonsense Mutation (SNP) | VAF 12/140 reads (9%) | catalogued as rs397515401, CM122406, COSV60107754, COSV60115393; ClinVar: pathogenic; called by muse, mutect2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 53/162 reads (33%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- CSMD3 | c.4558T>G p.F1520V (on ENST00000297405 / NM_001363185.1; = p.F1416V on NM_052900.3) | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52268332; called by muse, mutect2
- DBH | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs781667738; called by muse, mutect2, varscan2
- DIRAS1 | c.28G>T p.V10L | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.998); catalogued as COSV60215805; called by muse, mutect2
- IPO7 | c.200A>G p.Y67C | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as COSV65684130; called by muse, mutect2, varscan2
- KALRN | c.2438G>A p.R813H | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.98); PolyPhen probably damaging (0.997); catalogued as rs367667422; called by muse, mutect2, varscan2
- OR7C2 | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.317); catalogued as rs1197723389; called by muse, mutect2, varscan2
- PLXNA4 | c.4910G>A p.R1637Q | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs753325197, COSV58127821; called by muse, mutect2, varscan2
- TAF4 | c.2485C>T p.R829W | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs376636061; called by muse, mutect2, varscan2
- WT1 | c.1101_1102insGGGGC p.R368Gfs*71 | Frame Shift Ins (INS) | VAF 38/176 reads (22%) | catalogued as COSV100189346, COSV60065589, COSV60066153, COSV60066283, COSV60067539, COSV60069909, COSV60077657, COSV60077667, COSV60077683, COSV60078403, COSV60079676, COSV60084998, COSV60085351; called by pindel, varscan2
- WT1 | c.1069delinsGG p.R357Gfs*16 | Frame Shift Ins (INS) | VAF 38/181 reads (21%) | catalogued as CM971594, COSV60067818, COSV60068249, COSV60071382, COSV60073329, COSV60074859, COSV60075137; called by pindel, varscan2*
- ANKHD1-EIF4EBP3 | c.3980_3981insTGAGATACTG p.P1328Efs*15 | Frame Shift Ins (INS) | VAF 5/49 reads (10%) | called by mutect2, pindel, varscan2
- CREBBP | c.2641C>T p.Q881* | Nonsense Mutation (SNP) | VAF 8/214 reads (4%) | called by muse, mutect2
- NINJ1 | c.277G>T p.G93C | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2
- PLXNB1 | c.2633T>C p.L878P | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, varscan2
- PTGES | c.350A>G p.Y117C | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SETD2 | c.7573A>T p.K2525* | Nonsense Mutation (SNP) | VAF 31/71 reads (44%) | called by muse, mutect2, varscan2
- CRACD | c.822C>A p.G274= | Silent (SNP) | VAF 4/32 reads (13%) | called by muse, varscan2
- KCNH2 | c.30G>T p.P10= | Silent (SNP) | VAF 4/29 reads (14%) | called by muse, mutect2, varscan2
- LCAT | c.66C>T p.A22= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs910206058; called by muse, mutect2, varscan2
- VKORC1 | c.173+130A>G | Intron (SNP) | VAF 32/93 reads (34%) | called by muse, mutect2, varscan2
